Somatic mutation profile of tumor specimen TCGA-G9-6499-01A (aliquot TCGA-G9-6499-01A-12D-1961-08) from TCGA case TCGA-G9-6499, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,388 days).
Specimen TCGA-G9-6499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28fa694f-ed08-4144-a06d-d617a8d142b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6499-10A (Blood Derived Normal), aliquot TCGA-G9-6499-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5733ca1e-8065-4565-b095-852c11b5b125

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Frame Shift Del 3, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.526T>C p.C176R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967461896, CM165714, COSV52681947, COSV52682539, COSV52736779, COSV52752470; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL2 | c.482T>A p.L161H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63206859; called by muse, mutect2, varscan2
- ARHGEF11 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV100810193, COSV63816030; called by muse, mutect2, varscan2
- ASCC2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs772979948, COSV57072978; called by muse, mutect2
- ATP6V0A2 | c.571A>C p.M191L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV57752835; called by muse, mutect2, varscan2
- CD248 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765951466, COSV60935797, COSV60937390, COSV60938104; called by muse, mutect2, varscan2
- CDCA7L | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301630062, COSV60966655, COSV60982391; called by muse, mutect2
- CDK13 | c.3580C>G p.Q1194E | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV51707583; called by muse, mutect2, varscan2
- CEP76 | c.1486A>G p.I496V | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs903278909, COSV50871210; called by muse, mutect2, varscan2
- CNPY4 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 83/290 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs933974511, COSV53542735; called by muse, mutect2, varscan2
- FANCD2OS | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55047903; called by muse, mutect2, varscan2
- GRIA2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1408962625, COSV52409063; called by muse, mutect2, varscan2
- GRIP2 | c.1069G>C p.G357R (on ENST00000619221; = p.G260R on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56125565; called by muse, mutect2, varscan2
- ITGB4 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52334224; called by muse, mutect2, varscan2
- LILRA1 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52185892; called by muse, varscan2
- NWD1 | c.3157T>G p.S1053A | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV60353442; called by muse, mutect2
- PCDHA12 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.59); catalogued as COSV56553055; called by muse, mutect2, varscan2
- PCSK6 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as rs756408332, COSV60171383; called by muse, mutect2, varscan2
- SGCD | c.215C>G p.T72R (on ENST00000435422 / NM_001128209.2; = p.T73R on NM_000337.5) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV61918182; called by muse, mutect2, varscan2
- SMAD6 | c.1276G>T p.V426F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV56598125; called by mutect2, varscan2
- TRIO | c.8842T>C p.Y2948H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.444); catalogued as COSV59992832; called by muse, mutect2, varscan2
- TRIP4 | c.1670C>G p.P557R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.39); catalogued as COSV56033906; called by muse, mutect2, varscan2
- TUBGCP6 | c.3844C>G p.L1282V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.088); catalogued as COSV50597357; called by muse, mutect2, varscan2
- VPS13C | c.8602C>G p.L2868V (on ENST00000644861 / NM_020821.3; = p.L2825V on NM_017684.5) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs192667052, COSV51428566; called by muse, mutect2, varscan2
- ZC3H3 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV52795491; called by muse, mutect2, varscan2
- ARID2 | c.4196del p.L1399* | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- CD63 | c.516del p.N172Kfs*28 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel, varscan2
- INO80 | c.3029dup p.L1010Ffs*19 | Frame Shift Ins (INS) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- TSPAN7 | c.163del p.S55Pfs*34 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- CLK2 | c.132G>A p.R44= | Silent (SNP) | VAF 19/252 reads (8%) | catalogued as COSV62878378; called by muse, mutect2
- GABRR1 | c.1324A>C p.R442= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV65620995; called by muse, mutect2, varscan2
- IRF8 | c.33A>C p.R11= | Silent (SNP) | VAF 35/232 reads (15%) | catalogued as COSV51901207; called by muse, mutect2, varscan2
- NCAM2 | c.1278G>A p.S426= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs766563778, COSV53107803; called by muse, mutect2, varscan2
- OR6T1 | c.891G>T p.V297= | Silent (SNP) | VAF 32/358 reads (9%) | catalogued as COSV58309920; called by muse, mutect2
- SLC44A5 | c.462G>A p.K154= | Silent (SNP) | VAF 19/239 reads (8%) | catalogued as COSV63775942; called by muse, mutect2
- TYW1 | c.918G>A p.Q306= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as rs1191172509, COSV62756967; called by muse, mutect2
- ZNF571 | c.1050G>A p.L350= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100143439, COSV60734948; called by muse, mutect2, varscan2
- BABAM2 | c.1089-11091C>G | Intron (SNP) | VAF 30/223 reads (13%) | catalogued as COSV59634248; called by muse, mutect2, varscan2
